Surgical pathology report (de-identified scan), TCGA case TCGA-D7-8574, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-8574-01A (Primary Tumor).

Material:

1) Material: stomach, Method of collection: Total organ resection

Histopathological diagnosis:

Examination performed on:

Gastric adenocarcinoma mucocellulare with metastases to lymph nodes (13 /16). G3, pT2, pN2.

Macroscopic description:

The specimen containing the stomach, after being incised along the greater curvature sized 21.5 x 17 cm with the omentum sized 48 x 32cm. Tumour sized 3.2 x 5.5 x 1.4 cm found in the pyloric region. Distance from the proximal end: 7.1.cm, from distal end: 2.5 cm.

Microscopic description:

Gastric adenocarcinoma mucocellulare (diffuse type); the tumour infiltrates deep into the muscular membrane (pT2). Incision lines free of neoplastic lesions. Cancer metastases to 13/16 lymph nodes was found.

Assistant:

Pathologist:

**HER2 protein stained with Ventana Pathway HER-2/neu (4B5) Rabbit Monoclonal Antibody.
Negative reaction in invasive cancerous cells (Score = 1+)**

Assistant:

Pathologist :

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 8a3b523f-6cd8-49c2-bdd0-45e69f89644b (TCGA-D7-8574.6666BBE7-2F3B-40D3-9B3D-7B9396F97CDA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).